Somatic mutation profile of tumor specimen MMRF_1731_2_BM_CD138pos (aliquot MMRF_1731_2_BM_CD138pos_T1_KHS5U_L14851) from MMRF case MMRF_1731, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.9 years (18,588 days).
Specimen MMRF_1731_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b05d3ce-a3ea-4cd8-b522-4cac9d702b31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1731_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1731_1_PB_Whole_C3_KBS5U_L06469; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/842f5482-9b23-4c5e-9bd9-6bdccdece82f

The open-access MAF lists 65 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 22, Missense Mutation 20, Intron 8, Silent 6, Nonsense Mutation 3, 3'Flank 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL7R | c.361dup p.I121Nfs*8 | Frame Shift Ins (INS) | VAF 23/142 reads (16%) | catalogued as rs869312857; ClinVar: pathogenic; called by mutect2, varscan2
- BICD2 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1345664005; called by muse, mutect2, varscan2
- EPHX3 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326353175; called by muse, mutect2, varscan2
- FAM83H | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs371718430; called by muse, mutect2, varscan2
- FPR2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766221747, COSV60673878; called by muse, mutect2, varscan2
- GABRB3 | c.1178T>A p.I393K | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as COSV54664765; called by muse, mutect2, varscan2
- IGLV3-1 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs185803370; called by muse, mutect2, varscan2
- LIMCH1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760768105, COSV58302319; called by muse, mutect2, varscan2
- NEO1 | c.4122del p.Y1375Mfs*16 | Frame Shift Del (DEL) | VAF 35/147 reads (24%) | catalogued as COSV99982378; called by mutect2, pindel, varscan2
- RRAD | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55336432; called by muse, mutect2
- SNX14 | c.2425C>T p.H809Y (on ENST00000314673 / NM_001350535.1; = p.H756Y on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1220817629; called by muse, mutect2, varscan2
- ADGRD2 | c.2522-6C>A | Splice Region (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- CCHCR1 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- COL11A2 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EYS | c.7651del p.Y2551Mfs*2 | Frame Shift Del (DEL) | VAF 46/245 reads (19%) | called by mutect2, pindel, varscan2
- FNDC1 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ITPR1 | c.3916A>G p.N1306D (on ENST00000354582; = p.N1291D on NM_002222.7) | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KALRN | c.3869T>C p.L1290P | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA1 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 51/206 reads (25%) | called by muse, mutect2, varscan2
- LGI3 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MASTL | c.1805C>G p.S602* | Nonsense Mutation (SNP) | VAF 32/155 reads (21%) | called by muse, mutect2, varscan2
- MEX3B | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYO1F | c.3022C>A p.L1008I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- PIWIL4 | c.1960A>G p.I654V | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PTPRQ | c.4061C>G p.S1354C (on ENST00000616559; = p.S1312C on NM_001145026.2) | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SLC7A13 | c.1261C>A p.H421N | Missense Mutation (SNP) | VAF 112/535 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- SNAP25 | c.406A>G p.R136G | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- ABCC12 | c.1809C>T p.L603= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as rs770598854, COSV60913554; called by muse, mutect2, varscan2
- CCND1 | c.186C>A p.T62= | Silent (SNP) | VAF 59/140 reads (42%) | called by muse, varscan2
- CDC37 | c.960C>T p.A320= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as rs763402340; called by muse, mutect2, varscan2
- FAM234B | c.762C>T p.N254= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs759389681, COSV52193770; called by muse, mutect2, varscan2
- NPTX2 | c.693C>T p.L231= | Silent (SNP) | VAF 43/206 reads (21%) | catalogued as COSV55719177; called by muse, mutect2, varscan2
- TRAM1L1 | c.1023T>G p.S341= | Silent (SNP) | VAF 60/292 reads (21%) | called by muse, mutect2, varscan2
- ACP5 | c.262-19C>G | Intron (SNP) | VAF 52/218 reads (24%) | called by muse, mutect2, varscan2
- ARID5B | c.*544C>T | 3'UTR (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- CACNA1G | c.*210A>G | 3'UTR (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- CARS1 | c.*140C>T | 3'UTR (SNP) | VAF 36/116 reads (31%) | catalogued as rs192795142; called by muse, mutect2, varscan2
- CCDC198 | c.*269T>C | 3'UTR (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2, varscan2
- CCSER1 | c.2011-33882A>C | Intron (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- DIPK1B | c.199-863G>C | Intron (SNP) | VAF 30/190 reads (16%) | called by muse, mutect2, varscan2
- DPT | c.*1069T>G | 3'UTR (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- ETS1 | chr11:128458812 A>G | 3'Flank (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- FLRT2 | c.*2080C>T | 3'UTR (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- GABRA2 | chr4:46249314 A>G | 3'Flank (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- H2AC20 | c.*9A>T | 3'UTR (SNP) | VAF 54/331 reads (16%) | called by muse, mutect2, varscan2
- HEPHL1 | c.*683T>G | 3'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- HGF | c.865+656dup | Intron (INS) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- HIC2 | c.*3353G>T | 3'UTR (SNP) | VAF 23/96 reads (24%) | catalogued as COSV68042017; called by muse, mutect2, varscan2
- INTS3 | c.*817C>A | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- LIG3 | c.1456-34G>T | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, varscan2
- MGAT4A | c.*3822A>G | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- NPTX2 | c.*91T>A | 3'UTR (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- PABPC3 | c.*673T>C | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2431+264dup | Intron (INS) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB5 | c.*18G>A | 3'UTR (SNP) | VAF 60/258 reads (23%) | catalogued as rs1299109959, COSV50649508; called by muse, mutect2, varscan2
- PI15 | c.*2681C>T | 3'UTR (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99477996; called by muse, mutect2, varscan2
- PLPP6 | c.*97C>T | 3'UTR (SNP) | VAF 52/187 reads (28%) | called by muse, mutect2, varscan2
- RFX4 | c.994-18G>A | Intron (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- TEDDM1 | c.*661A>G | 3'UTR (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- TENT4A | c.*74C>T | 3'UTR (SNP) | VAF 14/74 reads (19%) | catalogued as rs896598811; called by muse, mutect2, varscan2
- TKFC | c.1576-19C>G | Intron (SNP) | VAF 40/149 reads (27%) | called by muse, mutect2, varscan2
- TMEM30B | c.*2544C>T | 3'UTR (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- TP73 | c.*489T>C | 3'UTR (SNP) | VAF 80/309 reads (26%) | called by muse, mutect2, varscan2
- TRIM66 | c.*4223A>G | 3'UTR (SNP) | VAF 12/60 reads (20%) | catalogued as rs961650902; called by muse, mutect2, varscan2
- ZNF396 | c.*2237T>G | 3'UTR (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
